TARGET case TARGET-10-PANWIM — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bdc57f00-7b5b-552e-b682-abf5d40e324a

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Age at index: 2 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 2.7 years (1,004 days); Year of diagnosis: 2005; Days to last follow up: 2,952 days (8.1 years).
   Treatment given: Protocol identifier: AALL0331.

Follow-up (1 entry)
- Days to follow up: 2,952 days (8.1 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,952; Year of follow up: 2013.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Positive.
- Day 0: Leukocytes 30.3 ×10³/µL.
- Day 8: Bone Marrow blast count 34%.
- Day 15: Bone Marrow blast count 2%.
- Day 29: Bone Marrow blast count 3%; Minimal Residual Disease (Flow Cytometry) 0%.

Biospecimens (2 samples)
- Sample TARGET-10-PANWIM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PANWIM-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_Blast_Data_20230727.xlsx, for sample TARGET-10-PANWIM-09A-01D:
- Blast %: Yes many

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Validation_20230727.xlsx:
- Overall Survival Time in Days: 2952
- WBC at Diagnosis: 30.3
- CNS Status at Diagnosis: CNS 1
- MRD Day 29: 0
- MRD Day 29 Sensitivity: 0.01
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Positive
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 34
- BMA Blasts Day 15: 2
- BMA Blasts Day 29: 3
- Down Syndrome: No
- DNA Index: 1
- Cell of Origin: B Cell ALL
